Gene-level copy-number profile of tumor specimen TCGA-75-5125-01A from TCGA case TCGA-75-5125, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-75-5125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.78977eda-a503-44e9-af62-a3ccd1a1ab88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-75-5125-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e569e24-0008-40e5-a3cc-bb6414a735ae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 856; copy number 3: 8,061; copy number 4: 15,250; copy number 5: 10,965; copy number 6: 12,379; copy number 7: 3,608; copy number 8: 6,061; copy number 9: 1,221; copy number 10: 957; copy number 11: 453; copy number 13: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-75-5125-01A-01D-1752-01): tumor purity 0.31, ploidy 3.69, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,633 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–30,365,684, 453 genes, copy number 11 (broad region; genes not listed).
- chr6:109,978,256–170,738,536, 956 genes, copy number 10 (broad region; genes not listed).
- chr8:46,028,804–46,028,892, 1 gene, copy number 10: AC118650.1.
- chr8:46,579,213–73,878,854, 418 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:74,599,775–74,823,313, 1 gene, copy number 9 (within-gene range 5–9): MIR2052HG.
- chr8:74,705,693–131,432,869, 804 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
